Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5743, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5743-01A (Primary Tumor).

CGA-CH-5743

Diagnosis

1. Predominantly moderately differentiated bilateral adenocarcinoma of the prostate in the peripheral zone (Gleason 3+4=7; Gleason 4: 5%). Maximum tumor diameter 1.6 cm. No tumor infiltration of the periprostatic fatty tissue. Tumor involvement of a few perineural sheaths. No evidence of blood or lymph vessel invasion.

Tumor-free surgical preparation margins.

In addition, foci of a prostatic intraepithelial neoplasia (high-grade PIN) and signs of myoglandular prostatic hyperplasia. Urothelium of prostatic urethra without dysplasia. Tumor-free, regular seminal vesicles and seminal ducts.

2. Lymph nodes right: a tumor-free lymph node (0/1).

Summary tumor classification

pT2c, max. tumor diameter 16 mm, Gleason 3+4=7 (5% Gleason 4). L0/V0, pN0 (0/1), R0.

Source: NCI Genomic Data Commons file 615ab801-d324-431d-b7cf-9e1f34faea8c (TCGA-CH-5743.E4F18F30-A6F0-4262-8F34-CE32DB5CBE4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).